Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A1GE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A1GE-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

ICD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C 54.1

1/31/11
lw

Diagnosis:

A: Tube and ovary, right, salpingo-oophorectomy

- Right ovary with serous cystadenoma
- Right fallopian tube without diagnostic histopathologic change
- No malignancy identified

B: Uterus and cervix, hysterectomy:

Location of tumor: Endometrium

Histologic type: Endometrioid adenocarcinoma with squamous differentiation arising in complex atypical hyperplasia

Histologic grade (FIGO): 1 (architecture grade 1, nuclear grade 2)

Extent of invasion: Tumor is limited to endometrium

Myometrial invasion: Not identified

Serosal involvement: Not identified

Lower uterine segment involvement: Not identified

Cervical involvement: Not identified

Adnexal involvement (see below): Not identified

Cervical/vaginal margin and distance: Widely negative

Lymphovascular Space Invasion: Not identified

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 37

Other Pathologic findings:

Cervix Benign endocervical polyp; acute and chronic inflammation

Myometrium Adenomyosis

Print Malignancy History		X
Dual/Synchronous Primary	Noted	DISQUALIFIED
Case is (re)filed:	QUALIFIED	

[page 2 of 5]
Tumor estrogen receptor and progesterone receptor immunohistochemistry results: pending; will be issued in an addendum report

AJCC Pathologic stage (Updated 2008 FIGO staging classification): pT1a pN0 pMx

FIGO (2008 classification) Stage grouping: IA

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, left, oophorectomy:

- Endometriosis
- Epithelial inclusion cysts
- Stromal hyperplasia

Fallopian tube, left, salpingectomy:

- No diagnostic histopathologic change

C: Lymph node, right peri-aortic, removal

- No carcinoma identified in five lymph nodes (0/5)

D: Lymph node, left peri-aortic, removal

- No carcinoma identified in five lymph nodes (0/5)

E: Lymph node, right pelvic, removal

- No carcinoma identified in twelve lymph nodes (0/12)

F: Lymph node, left pelvic, removal

- No carcinoma identified in fifteen lymph nodes (0/15)

Clinical History:

with endometrial cancer.

Gross Description:

Received are six appropriately labeled containers.

Container A is additionally labeled "right tube and ovary." It holds a 127.5 gram intact 9.3 x 9.2 x 2.1 cm cyst with an attached 7.5 x 0.6 cm fimbriated fallopian tube. The external surface of the cyst is smooth, pink/tan and glistening. Opening the cyst reveals a unilocular cyst containing thin serous fluid. The lining of the cyst is smooth and glistening with no papillations or excrescences appreciated. There are no solid areas appreciated. There are several smaller cysts within the cyst wall which average 0.1 cm in thickness. Representative sections are submitted in blocks A1-A6.

Container B:

[page 3 of 5]
Adnexa: The left adnexa is received attached to the specimen.

Weight: 450 grams

Shape: pear shaped

Dimensions:

height: 15.5 cm

anterior to posterior width: 7.5 cm

breadth at fundus: 10.5 cm

Serosa: smooth, glistening, tan/pink with areas of erythema; The posterior serosa is received markedly superficially disrupted into the myometrium.

Cervix:

length of endocervical canal: 3.7 cm

ectocervix: white/pink, smooth and glistening with multiple mucus-filled cysts and focal erythema

endocervix: trabecular, yellow and glistening with a 2.4 x 1.4 x 0.6 cm

fleshy endocervical polyp on the anterior surface

Endomyometrium:

length of endometrial cavity: 7.7 cm

width of endometrial cavity at fundus: 6.5 cm

tumor findings:

dimensions: 8 x 7.5 x 2.5 cm

appearance: fleshy, shaggy, tan/pink

location and extent: The tumor occupies both anterior and posterior surfaces and extends to the lower uterine segment; grossly, the tumor does not involve the endocervical canal.

myometrial invasion: no apparent invasion

thickness of myometrial wall at deepest gross invasion: 3.2 cm; The myometrium is markedly thinned with no intramural masses or nodules appreciated. No gross invasion is appreciated.

other findings or comments: none

Adnexa:

Left ovary:

dimensions: 2.4 x 1.2 x 0.9 cm

external surface: smooth, tan/pink and glistening

cut surface: grossly unremarkable

Left fallopian tube:

dimensions: 5.7 x 0.5 cm

other findings: There is a patent lumen on sectioning.

Lymph nodes: submitted separately

Other comments: none

Digital photograph taken: no

Tissue submitted for special investigations: Tumor is given to Tissue Procurement.

[page 4 of 5]
Block Summary:

B1 - anterior cervix

B2 - anterior endocervical canal with polyp

B3-B4 - full thickness section of body, bisected; superficial and deep, respectively

B5-B6 - full thickness section, fundus, bisected; superficial and deep, respectively

B7 - posterior cervix

B8 - posterior endocervical canal with lower uterine segment

B9-B10 - posterior endomyometrium/body

B11-B12 - posterior endomyometrium/fundus

B13 - left adnexa, representative

Container C is additionally labeled "right peri-aortic lymph node." It holds a 4 x 3 x 2 cm aggregate of yellow/tan cauterized fibrofatty tissue containing lymph node candidates measuring up to 2.1 cm in greatest dimension.

Block summary:

C1 - three lymph node candidates

C2 - one lymph node candidate, bisected

C3 - one lymph node candidate, sectioned

C4-C5 - remainder of fat, i.

Container D is additionally labeled "left peri-aortic lymph node." It holds a 4.3 x 2.2 x 0.9 cm aggregate of focally cauterized lobulated yellow/tan fibrofatty tissue containing lymph node candidates measuring up to 1.2 cm in greatest dimension.

Block Summary:

D1 - two lymph node candidates

D2 - one lymph node candidate

D3 - remainder of fat,

Container E is additionally labeled "right pelvic lymph node." It holds a 5.2 x 4.8 x 1.8 cm aggregate of cauterized yellow/tan fibrofatty tissue which is dissected for lymph node candidates. Fatty lymph node candidates measuring up to 4.8 cm in greatest dimension are identified.

Block summary:

E1 - five lymph node candidates

E2 - one lymph node candidate

E3-E4 - one lymph node candidate, bisected

E5-E8 - one lymph node candidate, sectioned

E9-E12 - remainder of fat, *

Container F is additionally labeled "left pelvic lymph node." It holds a 6.8 x 5.2 x 1.6 cm aggregate of focally cauterized yellow/tan fibrofatty tissue which is dissected for lymph node candidates. Multiple fatty replaced lymph node candidates are identified. Lymph node candidates measuring up to 3.7 cm in greatest dimension are identified.

[page 5 of 5]
Block summary:

F1 - four lymph node candidates

F2 - two lymph node candidates

F3 - two lymph node candidates

F4 - one lymph node candidate

F5 - one lymph node candidate, bisected

F6-F7 - one lymph node candidate, bisected

F8-F9 - one lymph node candidate, sectioned

F10-F16 - remainder of fat, ...

Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Resident Physician:

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Procedures/Addenda:

Addendum

Addendum

Immunohistochemical studies for estrogen and progesterone receptors are performed; the results are as follows:

Estrogen receptor: Approximately 80% of tumor cells show moderate (2+/3) nuclear staining.

Progesterone receptor: Approximately 10-20% of cells show weak or moderate (1+ or 2+/3) nuclear staining.

Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the (

These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 451201f3-3184-4ca9-bce2-131badbe88f1 (TCGA-EY-A1GE.432813D0-4B52-4941-940C-5725BCE4211A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).